Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RE-01A (Primary Tumor).

Specimen Comments

SPECIMEN

Bladder tumour.

CLINICAL DETAILS

Samples taken for research. Persistent G3 pT2 TCC.

MACROSCOPY

18g of firm and friable tissue chippings.

MICROSCOPY

Grade: 3 poorly differentiated.

Growth pattern: Mixed papillary and solid.

Type: Transitional cell carcinoma.

Muscularis propria present: Yes.

Stromal invasion: Invasion of muscularis propria (at least).

Vascular channel invasion: No definite lymphovascular invasion.

Background urothelium: Carcinoma in situ is present in flat urothelium.

Summary: Transitional cell carcinoma G3 pT2 (at least).

Pathologists -

CSCE ICD-O-3
Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site: Bladder NOS 067.9
9/5/2/14

Dual/Synchronous Primary		Noted

Source: NCI Genomic Data Commons file 9c17aab5-6185-467e-9d88-8e0b57233a54 (TCGA-ZF-A9RE.9AF70357-D696-4AEB-B338-7A711A39DAE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).